Surgical pathology report (de-identified scan), TCGA case TCGA-A6-6649, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-6649-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

Right colon resected at [REDACTED]

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right colon cancer

GROSS DESCRIPTION

Received fresh labeled "right colon" is a previously unopened 30 cm. segment of proximal right colon with attached 8 cm. of distal ileum surfaced by smooth tan pink serosa with a copious amount of attached, mesocolon, mesentery, and unremarkable omentum. No appendix is identified. The proximal and distal margins measure 4.0 and 8.0 cm. in circumference respectively. On opening, there is a moderately well circumscribed, 4.5 x 3.8 cm. rubbery tan white-pink tumor mass located 9 cm. distal to the ileocecal valve. A portion of tumor and a portion of normal mucosa are submitted for tissue procurement as requested. On sectioning, the tumor has a maximal thickness of 1.8 cm., grossly extending into the muscularis to within 0.6 cm. of the inked free radial serosal surface. A few soft tan ink polypoid lesions measuring up to 0.6 cm. in greatest dimension are present throughout the remainder of the colon. The ileal and remaining colonic mucosa is unremarkable, glistening tan pink with regular folds and the walls average 0.5 cm. in thickness. Multiple soft to slightly rubbery pale tan to tan-red tissues in keeping with lymph nodes measuring up to 1.2 cm. in greatest dimension are recovered from the attached mesocolon and mesentery. Representative sections are submitted in 15 blocks as labeled. RS-15.

BLOCK SUMMARY: 1 - Proximal and distal margins; 2, 3 - tumor full thickness to inked free radial serosal surface; 4 - central tumor; 5 - tumor to normal mucosa; 6, 7 - colonic polyps; 8 - ICV; 9 - random colon; 10-12 - six whole lymph nodes per cassette; 13-15 - one bisected lymph node per cassette. [REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Primary tumor (pT): Tumor invades through the full thickness of the wall into the adjacent adipose tissue, pT3
Proximal margin: Negative for tumor
Distal margin: Negative for tumor
Circumferential (radial) margin: Tumor is not identified at the outer serosal surface of the specimen.
Distance of tumor from closest margin: 21 cm from distal margin of excision
Vascular invasion: Present in pericolonic tissue
Regional lymph nodes (pN): Two of twenty-three lymph nodes positive for metastatic carcinoma (2/23), pN1b
Non-lymph node pericolonic tumor: Perineural invasion by tumor is identified

[page 2 of 2]
Distant metastasis (pM): pMX

Other findings: Separate adenomatous polyps are identified within the colon.

5x1

DIAGNOSIS

Colon, right, excision - Invasive poorly differentiated adenocarcinoma (see tumor characteristics in the colon resection template in the microscopic description).

--- End Of Report ---

Source: NCI Genomic Data Commons file 6a4f55bd-55a6-478d-9a1b-aea95d11e650 (TCGA-A6-6649.FEE7EE02-806C-463A-9841-5758C737207A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).